Somatic mutation profile of tumor specimen ALCH-B3ES-TTP1-A (aliquot ALCH-B3ES-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3ES, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 51.3 years (18,754 days).
Specimen ALCH-B3ES-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92ca9b19-8d01-4dfd-b03d-4eb1d3daa2f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ES-NB1-A (Blood Derived Normal), aliquot ALCH-B3ES-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77461d46-011b-4890-88fe-2edf3be0c3fb

The open-access MAF lists 160 somatic variants for this specimen: 105 protein-altering or splice-affecting, 40 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 40, Nonsense Mutation 7, Intron 5, 3'UTR 4, RNA 3, Splice Site 2, 3'Flank 2, Translation Start Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 192/596 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 48/252 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.537C>A p.H179Q | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); catalogued as rs80268015; called by muse, mutect2, varscan2
- ALPK2 | c.2783G>T p.G928V | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1010188528; called by muse, mutect2, varscan2
- AP4M1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs773269627, COSV100385147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10B | c.603T>A p.H201Q | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777199291; called by muse, mutect2
- CCDC57 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.501); catalogued as rs1324765642; called by muse, mutect2
- CFAP47 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52885780; called by muse, mutect2
- CHD7 | c.6033G>T p.L2011F | Missense Mutation (SNP) | VAF 54/603 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101418433; called by muse, mutect2
- CNTRL | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs139202415; called by muse, mutect2
- COL21A1 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV55172434; called by muse, mutect2, varscan2
- CSMD3 | c.8029G>A p.D2677N (on ENST00000297405 / NM_001363185.1; = p.D2573N on NM_052900.3) | Missense Mutation (SNP) | VAF 59/540 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV52160940; called by muse, mutect2, varscan2
- DNAH5 | c.2048G>T p.R683L | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as COSV54204006; called by muse, mutect2, varscan2
- EFNB1 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1251392015, COSV52661077; called by muse, varscan2
- EPHA5 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56682730; called by muse, mutect2
- FREM2 | c.6169+1G>T p.X2057_splice | Splice Site (SNP) | VAF 34/276 reads (12%) | catalogued as COSV99748010; called by muse, mutect2, varscan2
- FTSJ3 | c.2488_2490del p.K830del | In Frame Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs759856668; called by pindel, varscan2
- IGHV3OR16-9 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 43/686 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs780973245; called by muse, mutect2
- LRRC74B | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as rs1375565081; called by muse, mutect2
- LTBP2 | c.5147C>G p.P1716R | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100000797; called by muse, mutect2
- MDM1 | c.108G>T p.W36C | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100291805; called by muse, mutect2
- MUC13 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV60701117; called by mutect2, varscan2
- NCOR1 | c.395C>G p.P132R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as COSV51995901, COSV51997485, COSV52003388; called by muse, mutect2, varscan2
- OR2L5 | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 32/363 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777371954; called by muse, mutect2
- PLCD3 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.408); catalogued as rs763019720; called by muse, mutect2, varscan2
- POLE | c.4307G>T p.R1436L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57674115; called by muse, mutect2, varscan2
- RFX6 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 22/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60589085; called by muse, mutect2
- SAMHD1 | c.1606C>T p.Q536* (on ENST00000262878 / NM_001363729.2; = p.Q571* on NM_015474.4) | Nonsense Mutation (SNP) | VAF 44/660 reads (7%) | catalogued as COSV53430849; called by muse, mutect2
- TAF1 | c.2743A>G p.T915A (on ENST00000373790 / NM_138923.4; = p.T936A on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99337585; called by muse, mutect2
- TEKT4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.123); catalogued as rs1553396650; called by muse, mutect2, varscan2
- TMEM151A | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1324573870; called by muse, mutect2
- TRMT12 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV100149078; called by muse, mutect2
- ZFHX3 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs773768765, COSV51736263; called by muse, mutect2, varscan2
- ZNF385D | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 23/285 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as rs750296631; called by muse, mutect2
- ZNF676 | c.872G>T p.G291V (on ENST00000650058; = p.G259V on NM_001001411.3) | Missense Mutation (SNP) | VAF 38/592 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV68092365; called by muse, mutect2
- ZNF729 | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as COSV62602043; called by muse, mutect2, varscan2
- ZNRF4 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1266151656, COSV55773900; called by muse, mutect2, varscan2
- ADAMTS12 | c.4460G>T p.C1487F | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 22/265 reads (8%) | called by muse, mutect2
- ANKFN1 | c.3734A>G p.Y1245C (on ENST00000653862; = p.Y1098C on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- APOE | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD99L2 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.054); called by muse, mutect2
- CNTNAP4 | c.3717C>A p.D1239E | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CPED1 | c.2566T>G p.L856V | Missense Mutation (SNP) | VAF 44/389 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPLX2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRISP1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2
- CTNND2 | c.1919C>G p.A640G | Missense Mutation (SNP) | VAF 26/532 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- DCAF5 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); called by muse, mutect2
- EDA2R | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 23/376 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); called by muse, mutect2
- FRMPD3 | c.4694A>T p.E1565V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, varscan2
- FSCB | c.2270C>A p.S757Y | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- GMCL2 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRAMD1B | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- GREB1L | c.445A>T p.K149* | Nonsense Mutation (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- GTSE1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HECTD2 | c.2289G>T p.L763F | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HELLS | c.2119A>T p.R707* | Nonsense Mutation (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- INPP5D | c.1639G>A p.E547K (on ENST00000445964 / NM_001017915.3; = p.E546K on NM_005541.5) | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAK2 | c.299A>T p.H100L | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KANSL1 | c.1913C>G p.S638* | Nonsense Mutation (SNP) | VAF 20/386 reads (5%) | called by muse, mutect2
- LAMA3 | c.3097C>T p.Q1033* | Nonsense Mutation (SNP) | VAF 65/641 reads (10%) | called by muse, mutect2, varscan2
- LRRC41 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); called by muse, mutect2
- MIEF1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2
- MPEG1 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MSH4 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MTRR | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/608 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- MYH7 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- NDC80 | c.1690T>C p.Y564H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2
- NMUR2 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- NOMO1 | c.3649C>A p.Q1217K | Missense Mutation (SNP) | VAF 30/748 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2
- NONO | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); called by muse, mutect2
- NOS3 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NUP205 | c.203A>T p.Q68L | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR2T10 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- OR5D14 | c.711C>A p.H237Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PANK1 | c.1277C>G p.S426C (on ENST00000307534 / NM_148977.2; = p.S201C on NM_138316.4) | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDHGB2 | c.1119C>A p.D373E | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHF6 | c.909C>A p.Y303* | Nonsense Mutation (SNP) | VAF 38/214 reads (18%) | called by muse, mutect2, varscan2
- PLCH2 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PLEC | c.4449G>T p.E1483D (on ENST00000322810 / NM_201380.4; = p.E1373D on NM_000445.5) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHG4B | c.3599G>T p.S1200I (on ENST00000283426; = p.S1556I on NM_052909.5) | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PNCK | c.848C>G p.S283C (on ENST00000340888 / NM_001366975.1; = p.S366C on NM_001039582.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRAG1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.363); called by muse, mutect2
- RGSL1 | c.2417G>T p.R806L | Missense Mutation (SNP) | VAF 52/483 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RTL9 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.288); called by muse, mutect2
- RYR2 | c.9450-1G>T p.X3150_splice | Splice Site (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- SAMD14 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCARF2 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- SEC14L1 | c.1035G>T p.R345S | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIRPD | c.497G>C p.C166S | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- SLC26A6 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TAP1 | c.260T>A p.L87Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TAP2 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 15/474 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2
- TBC1D30 | c.1472G>T p.R491L (on ENST00000542120; = p.R328L on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.031); called by muse, mutect2
- TEX55 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TIMM13 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TKTL1 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); called by muse, mutect2
- TXLNA | c.669G>C p.E223D | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2
- UBE3C | c.1169A>C p.Y390S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2
- UNC80 | c.6386G>A p.R2129H | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UNC80 | c.9444C>A p.D3148E | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.936C>A p.H312Q | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VMP1 | c.1124T>C p.M375T | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- VTA1 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- ZP4 | c.1441A>T p.S481C | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ABCB1 | c.3720A>T p.A1240= | Silent (SNP) | VAF 51/924 reads (6%) | called by muse, mutect2
- AHNAK2 | c.11248C>T p.L3750= | Silent (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- ALPK2 | c.156C>A p.I52= | Silent (SNP) | VAF 21/333 reads (6%) | catalogued as COSV64494534; called by muse, mutect2
- ARHGAP25 | c.957G>T p.V319= (on ENST00000409202 / NM_001007231.3; = p.V311= on NM_014882.3) | Silent (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- ASPG | c.1002A>G p.L334= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs758897293; called by muse, mutect2, varscan2
- ATP11C | c.519C>T p.T173= | Silent (SNP) | VAF 13/368 reads (4%) | catalogued as COSV59561340; called by muse, mutect2
- CAMKK2 | c.1206C>T p.I402= | Silent (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- CD300A | c.540G>A p.P180= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as rs149741904, COSV60409974; called by muse, varscan2
- CEP170B | c.3198C>T p.H1066= (on ENST00000453495; = p.H995= on NM_015005.3) | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs371581289; called by muse, mutect2, varscan2
- CLCN2 | c.1572C>T p.L524= | Silent (SNP) | VAF 35/148 reads (24%) | called by muse, mutect2, varscan2
- CLEC18C | c.51C>T p.L17= | Silent (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- COL21A1 | c.669G>T p.V223= | Silent (SNP) | VAF 14/82 reads (17%) | called by mutect2, varscan2
- CYP2E1 | c.903A>G p.T301= | Silent (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- CYP4F8 | c.942A>T p.S314= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- FAM187B | c.1098G>T p.L366= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- GFER | c.489G>T p.R163= | Silent (SNP) | VAF 33/343 reads (10%) | called by muse, mutect2
- HMX2 | c.552C>A p.S184= | Silent (SNP) | VAF 18/225 reads (8%) | called by muse, mutect2
- IGSF1 | c.2904C>T p.F968= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2
- INTS7 | c.2715A>G p.T905= | Silent (SNP) | VAF 36/582 reads (6%) | catalogued as rs756472267; called by muse, mutect2
- ITGAE | c.933C>A p.T311= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as rs780795780; called by muse, mutect2, varscan2
- LRRFIP1 | c.1332G>T p.G444= (on ENST00000392000 / NM_001137552.2; = p.G420= on NM_004735.4) | Silent (SNP) | VAF 32/241 reads (13%) | called by muse, mutect2, varscan2
- MEIS1 | c.843A>G p.K281= | Silent (SNP) | VAF 26/377 reads (7%) | called by muse, mutect2
- MOCS2 | c.153C>G p.A51= | Silent (SNP) | VAF 41/539 reads (8%) | catalogued as COSV63741204; called by muse, mutect2
- NRP2 | c.1209G>C p.L403= | Silent (SNP) | VAF 44/544 reads (8%) | called by muse, mutect2
- PAX6 | c.949C>A p.R317= | Silent (SNP) | VAF 93/580 reads (16%) | catalogued as CM930573, COSV99570800; called by muse, mutect2, varscan2
- PCDH15 | c.5658T>C p.V1886= | Silent (SNP) | VAF 40/916 reads (4%) | called by muse, mutect2
- PCDHA10 | c.1107C>T p.A369= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- PCIF1 | c.1617C>T p.P539= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- PFAS | c.1869C>G p.T623= | Silent (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- PLEC | c.12738C>T p.I4246= (on ENST00000322810 / NM_201380.4; = p.I4136= on NM_000445.5) | Silent (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- SCARB1 | c.57A>G p.L19= | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- SCN5A | c.1347C>T p.T449= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV61132584; called by muse, mutect2, varscan2
- SHROOM3 | c.3699G>T p.A1233= | Silent (SNP) | VAF 29/260 reads (11%) | called by muse, mutect2, varscan2
- SLC39A12 | c.384C>A p.I128= | Silent (SNP) | VAF 27/361 reads (7%) | called by muse, mutect2
- SOGA1 | c.3360C>T p.P1120= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- TAF1L | c.3078A>T p.L1026= | Silent (SNP) | VAF 24/364 reads (7%) | catalogued as COSV54259433; called by muse, mutect2
- TTN | c.20580A>G p.L6860= (on ENST00000591111; = p.L5933= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- UNC13D | c.882G>A p.S294= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as rs760286447; ClinVar: likely benign; called by muse, mutect2, varscan2
- UTRN | c.6C>T p.A2= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- ZCCHC7 | c.222A>G p.L74= | Silent (SNP) | VAF 20/304 reads (7%) | called by muse, mutect2
- AC034105.4 | n.179C>A | RNA (SNP) | VAF 5/36 reads (14%) | called by mutect2, varscan2
- AC079612.1 | n.691C>T | RNA (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- ANKRD26P1 | n.1913T>A | RNA (SNP) | VAF 61/329 reads (19%) | called by muse, mutect2, varscan2
- CTTN | c.*504T>A | 3'UTR (SNP) | VAF 46/325 reads (14%) | called by muse, mutect2, varscan2
- DOCK2 | c.2799+34456G>A | Intron (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- FGFR3 | c.*637G>T | 3'UTR (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- GOSR2 | chr17:46940627 G>C | 3'Flank (SNP) | VAF 24/464 reads (5%) | called by muse, mutect2
- HTR2C | c.-79-11595C>A | Intron (SNP) | VAF 43/223 reads (19%) | catalogued as COSV99347906; called by muse, mutect2
- NRBP2 | c.1381+45G>C | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- PRR14L | chr22:31676859 T>C | 3'Flank (SNP) | VAF 22/188 reads (12%) | catalogued as rs369727426; called by muse, mutect2, varscan2
- RNU6-389P | chr7:55685306 C>G | 5'Flank (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- TNNT3 | c.715-740G>A | Intron (SNP) | VAF 18/212 reads (8%) | catalogued as rs1360517827; called by muse, mutect2
- XKR4 | c.806+60900C>T | Intron (SNP) | VAF 8/193 reads (4%) | called by muse, mutect2
- ZNF738 | c.*1179G>T | 3'UTR (SNP) | VAF 15/353 reads (4%) | called by muse, mutect2
- ZNF738 | c.*1180A>G | 3'UTR (SNP) | VAF 15/354 reads (4%) | called by muse, mutect2
